Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAGV, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Erasmus MC, specimen TCGA-2G-AAGV-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile

Internal postal address

E-mail

Date

Concerning

Postal address

Summary pathology report

Street address

Left orchidectomy; nonseminoma (MT 100%); tumor diameter unknown; tumor confined to testis; no angio-invasion; no invasion of rete testis.

Date of procurement (= date of orchidectomy):

ICD O-3
Teratoma, mature 9080/0
Site: @ Testis NOS C62.9
JW 3/7/14

pathologist

professor of pathology

Source: NCI Genomic Data Commons file c68cf23d-d58b-4d20-a2cd-3f86c9de019d (TCGA-2G-AAGV.2EC03EAA-490B-4FF9-9407-82BFEA7855C4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).